Somatic mutation profile of tumor specimen TCGA-DD-AACC-01A (aliquot TCGA-DD-AACC-01A-11D-A40R-10) from TCGA case TCGA-DD-AACC, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Combined hepatocellular carcinoma and cholangiocarcinoma; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 61.6 years (22,499 days).
Specimen TCGA-DD-AACC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be9d44b2-8d97-4750-b2ec-00e216b5b428.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AACC-10A (Blood Derived Normal), aliquot TCGA-DD-AACC-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0b0334d-ee89-463c-8273-55e205717aa6

The open-access MAF lists 94 somatic variants for this specimen: 74 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 18, Frame Shift Del 2, Intron 2, Splice Region 2, Frame Shift Ins 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACACB | c.6144G>T p.M2048I | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.204); catalogued as COSV100622434; called by muse, mutect2, varscan2
- ADGRA2 | c.2606C>A p.P869H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1240840102, COSV99604732; called by muse, mutect2, varscan2
- ANP32E | c.167C>T p.S56L | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1553841795, COSV58482175; called by muse, mutect2
- ARHGEF12 | c.1672A>C p.K558Q | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV100754705; called by muse, mutect2, varscan2
- ASNS | c.1336C>T p.H446Y | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as rs749209281, COSV99446002; called by muse, mutect2, varscan2
- B3GNT4 | c.592C>A p.L198M | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99928055; called by muse, mutect2, varscan2
- C1QTNF7 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 44/223 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372857232; called by muse, mutect2, varscan2
- CACTIN | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1346471359, COSV99698339; called by muse, mutect2, varscan2
- CADPS | c.402T>G p.N134K | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99336332; called by muse, mutect2, varscan2
- CAND1 | c.850A>G p.R284G | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.367); catalogued as COSV101598263; called by muse, mutect2, varscan2
- CDH23 | c.7747G>T p.A2583S | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV99819273; called by muse, mutect2
- CDH8 | c.2093A>G p.K698R | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100179918, COSV100183791; called by muse, mutect2, varscan2
- CDK1 | c.638T>C p.L213P | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100358774; called by muse, mutect2
- CFAP58 | c.864T>G p.N288K | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.207); catalogued as COSV100458775; called by muse, mutect2, varscan2
- CNOT1 | c.5136-2A>G p.X1712_splice | Splice Site (SNP) | VAF 11/92 reads (12%) | catalogued as COSV99799419; called by muse, mutect2, varscan2
- CPEB4 | c.2003A>T p.D668V | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99436770; called by muse, mutect2, varscan2
- CYLC1 | c.1615A>C p.K539Q | Missense Mutation (SNP) | VAF 8/242 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100254172; called by muse, mutect2
- DAGLB | c.394G>A p.G132S | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.084); catalogued as rs763592341, COSV99765692; called by muse, mutect2, varscan2
- DLC1 | c.830G>A p.C277Y | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV99361585; called by muse, mutect2, varscan2
- DZIP3 | c.2153A>G p.K718R | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.681); catalogued as COSV100847668; called by muse, mutect2, varscan2
- ERICH3 | c.1218dup p.P407Tfs*7 | Frame Shift Ins (INS) | VAF 11/77 reads (14%) | catalogued as rs1441349703; called by mutect2, pindel, varscan2
- FAM120A | c.2224C>T p.Q742* | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | catalogued as COSV99464695; called by muse, mutect2
- FFAR1 | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs956591250, COSV50051951; called by muse, mutect2, varscan2
- FGA | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.154); catalogued as COSV100120105, COSV100120725, COSV57399370; called by muse, mutect2
- FSD1 | c.426G>A p.M142I | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV55696343; called by muse, mutect2
- GABRG1 | c.787T>C p.F263L | Missense Mutation (SNP) | VAF 52/324 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.314); catalogued as COSV99777520; called by mutect2, varscan2
- GDAP1 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as rs779770529, COSV99619366; called by muse, mutect2
- GNA12 | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); catalogued as rs1417455995, COSV99282410; called by muse, mutect2
- GRIN2B | c.535T>A p.Y179N | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101662937; called by muse, mutect2
- HERC4 | c.1679T>C p.V560A | Missense Mutation (SNP) | VAF 47/337 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.111); catalogued as rs772847954, COSV99516670; called by muse, mutect2, varscan2
- HSPA9 | c.1150A>C p.I384L | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.009); catalogued as COSV99785268; called by muse, mutect2, varscan2
- ITGB5 | c.71G>C p.G24A | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV99950430; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.474A>G p.G158= | Splice Region (SNP) | VAF 8/118 reads (7%) | catalogued as COSV100583714; called by muse, mutect2
- KDM1B | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99924004; called by muse, mutect2, varscan2
- KIFC3 | c.1685A>C p.K562T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs1555598629, COSV101109102; called by muse, mutect2, varscan2
- LCTL | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 42/225 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100427156; called by muse, mutect2, varscan2
- MAP3K13 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as COSV99406558, COSV99408293; called by muse, mutect2, varscan2
- MAP3K7 | c.156A>T p.K52N | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100997875; called by muse, mutect2, varscan2
- MATN2 | c.70A>G p.R24G | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99645835; called by muse, varscan2
- MEGF10 | c.1655C>T p.P552L | Missense Mutation (SNP) | VAF 44/207 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99174764, COSV99174796; called by muse, mutect2, varscan2
- MEOX1 | c.300C>A p.D100E | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100233682; called by muse, mutect2, varscan2
- MGAT2 | c.1303A>G p.R435G | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100023448; called by muse, mutect2
- NOP2 | c.1613G>T p.R538L (on ENST00000322166 / NM_001258308.2; = p.R534L on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV100350853; called by muse, mutect2, varscan2
- NR1D2 | c.1433G>T p.G478V | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766722837, COSV100437313, COSV56992601; called by muse, mutect2, varscan2
- OR11H1 | c.644T>A p.F215Y | Missense Mutation (SNP) | VAF 29/227 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99421629; called by muse, mutect2, varscan2
- PCBP1 | c.748A>G p.M250V | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.109); catalogued as rs548418658, COSV100340064; called by muse, mutect2, varscan2
- PCDH8 | c.802C>A p.L268M | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100131288; called by muse, mutect2
- PCLO | c.12464A>G p.Y4155C | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs199931189, COSV100428260; called by muse, mutect2, varscan2
- PHACTR3 | c.528C>A p.H176Q | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100732262; called by muse, mutect2
- PLXNA4 | c.2162C>T p.T721M | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs377154325, COSV58105240; called by mutect2, varscan2
- POLQ | c.2769T>A p.F923L | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV99951752; called by muse, mutect2, varscan2
- RO60 | c.947A>G p.K316R | Missense Mutation (SNP) | VAF 43/286 reads (15%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.909); catalogued as COSV100814327; called by muse, mutect2, varscan2
- RSF1 | c.2587G>A p.E863K | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.318); catalogued as COSV100406948, COSV57843915; called by muse, mutect2, varscan2
- SH3BP5 | c.682A>G p.T228A | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV99508107; called by muse, mutect2
- SIPA1L2 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99477374; called by muse, mutect2, varscan2
- SLC39A10 | c.2310G>A p.M770I | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.444); catalogued as COSV100660514; called by muse, mutect2, varscan2
- SLC4A7 | c.216A>C p.K72N | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.156); catalogued as COSV99839289; called by muse, mutect2
- SPAG17 | c.3493G>T p.V1165L | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.104); catalogued as COSV100308204, COSV100308611; called by muse, mutect2, varscan2
- TACC2 | c.6868G>T p.G2290C (on ENST00000334433; = p.G368C on NM_006997.4) | Missense Mutation (SNP) | VAF 31/211 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99586701; called by muse, mutect2, varscan2
- TARS1 | c.574G>T p.G192W | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV99465550; called by muse, mutect2, varscan2
- TJP1 | c.4975C>T p.P1659S | Missense Mutation (SNP) | VAF 21/133 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100632403; called by muse, mutect2, varscan2
- TRRAP | c.3785A>G p.H1262R | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.177); catalogued as COSV100722101; called by muse, mutect2, varscan2
- TSHZ1 | c.1149G>T p.Q383H (on ENST00000580243 / NM_001308210.2; = p.Q338H on NM_005786.6) | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as COSV100433450; called by muse, mutect2
- TTC19 | c.186G>T p.A62= | Splice Region (SNP) | VAF 90/493 reads (18%) | catalogued as rs758114969, COSV99889995; called by muse, mutect2, varscan2
- UST | c.701T>A p.L234H | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100819779; called by muse, mutect2, varscan2
- ZBTB32 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1214931485, COSV52889899; called by muse, mutect2, varscan2
- ZNF185 | c.1486G>T p.G496C | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.21); catalogued as COSV100248212, COSV59276735; called by muse, mutect2, varscan2
- ZNF208 | c.2436A>C p.K812N | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV101236878; called by muse, mutect2, varscan2
- ZNF318 | c.3376G>C p.G1126R | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100545993, COSV100546415; called by muse, mutect2, varscan2
- ZNF471 | c.1831A>C p.K611Q | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as COSV100340421; called by muse, mutect2, varscan2
- ZNF574 | c.2542C>A p.H848N | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as COSV99725806; called by muse, mutect2, varscan2
- KLF15 | c.531_579del p.H178Lfs*35 | Frame Shift Del (DEL) | VAF 15/148 reads (10%) | called by mutect2, pindel
- MSH6 | c.158_173del p.A53Gfs*23 | Frame Shift Del (DEL) | VAF 12/82 reads (15%) | called by mutect2, pindel, varscan2
- ZNF658 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 27/265 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- AGL | c.3570T>G p.P1190= | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as COSV99648605; called by muse, mutect2, varscan2
- BCL6 | c.1488G>A p.T496= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as rs370060611; called by muse, mutect2, varscan2
- BCL9L | c.2502G>A p.K834= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV99418791; called by muse, mutect2, varscan2
- DDHD1 | c.729A>G p.E243= (on ENST00000323669; = p.E440= on NM_030637.3) | Silent (SNP) | VAF 22/165 reads (13%) | catalogued as COSV100079150; called by muse, mutect2, varscan2
- FYB1 | c.1620C>A p.I540= | Silent (SNP) | VAF 17/132 reads (13%) | catalogued as COSV100685019; called by muse, mutect2, varscan2
- GRM7 | c.1722C>T p.T574= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as rs763131797, COSV63145993; ClinVar: likely benign; called by muse, mutect2
- IREB2 | c.579G>A p.Q193= | Silent (SNP) | VAF 15/144 reads (10%) | catalogued as COSV99359083; called by muse, mutect2, varscan2
- MVP | c.864C>T p.V288= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as rs765833197, COSV100651505; called by muse, mutect2, varscan2
- OVCA2 | c.24G>T p.R8= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV99559448, COSV99559634; called by muse, mutect2, varscan2
- SLC12A2 | c.1839T>G p.S613= | Silent (SNP) | VAF 44/146 reads (30%) | catalogued as COSV99320640; called by muse, mutect2, varscan2
- SNX19 | c.9A>G p.T3= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV99772866; called by muse, mutect2, varscan2
- SPIDR | c.2691C>T p.C897= | Silent (SNP) | VAF 24/163 reads (15%) | catalogued as COSV99854375; called by muse, mutect2, varscan2
- STKLD1 | c.127C>T p.L43= | Silent (SNP) | VAF 24/118 reads (20%) | catalogued as COSV100911916; called by muse, mutect2, varscan2
- TAC1 | c.165C>A p.I55= | Silent (SNP) | VAF 23/133 reads (17%) | catalogued as rs763171892, COSV100071050, COSV100071257; called by muse, mutect2, varscan2
- THOC3 | c.60G>C p.S20= | Silent (SNP) | VAF 22/205 reads (11%) | catalogued as COSV99442021; called by muse, mutect2, varscan2
- VPS52 | c.1563C>T p.V521= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV101460412; called by muse, mutect2, varscan2
- VSX2 | c.693C>A p.P231= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as COSV100001505, COSV56216682; called by muse, mutect2, varscan2
- ZNF350 | c.75G>T p.L25= | Silent (SNP) | VAF 25/139 reads (18%) | catalogued as COSV99702400; called by muse, mutect2, varscan2
- AC058822.1 | c.1018-288111C>A | Intron (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2, varscan2
- PLEKHJ1 | c.321-10T>C | Intron (SNP) | VAF 4/66 reads (6%) | catalogued as COSV55553944, COSV99677648; called by muse, mutect2
